Gene-level copy-number profile of tumor specimen TCGA-R6-A8W5-01B from TCGA case TCGA-R6-A8W5, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.0 years (21,917 days).
Specimen TCGA-R6-A8W5-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.75a8bcb9-cac9-4fee-8757-bb802f4d355f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A8W5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32c16d54-0573-43b3-a6ad-b894ae5322f4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 167; copy number 2: 16,466; copy number 3: 30,215; copy number 4: 10,653; copy number 5: 1,159; copy number 6: 695; copy number 7: 222; copy number 8: 63; copy number 9: 78; copy number 10: 38; copy number 11: 7; copy number 14: 5; copy number 18: 4; copy number 23: 3; copy number 46: 5; copy number 60: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A8W5-01B-11D-A37B-01): tumor purity 0.5, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,360,024–116,932,238, 9 genes: LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901.
- chr9:68,705,240–69,009,176, 5 genes (within-gene range 0–2): PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 435 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,221,193–6,635,586, 20 genes, copy number 8 (within-gene range 5–8): ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3.
- chr1:44,405,194–44,844,082, 22 genes, copy number 8 (within-gene range 3–8): RNF220, MIR5584, TMEM53, ARMH1, RNU5F-1, RNU5D-1, KIF2C, AL592166.1, RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4, PLK3, TCTEX1D4, BTBD19, PTCH2, RNU5E-6P, AL136380.1.
- chr2:9,583,967–10,837,977, 38 genes, copy number 7 (within-gene range 3–7): YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261, RN7SL66P, AC007240.3, AC007240.2, HPCAL1, ODC1, SNORA80B, ODC1-DT, NOL10, AC007314.1, RN7SL832P, Metazoa_SRP, AC092687.2, ATP6V1C2, RNU7-138P, AC092687.3, PDIA6.
- chr2:44,361,947–45,612,165, 22 genes, copy number 7 (within-gene range 3–7): CAMKMT, LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1, KRTCAP2P1, SIX2, AC093702.1, LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P.
- chr2:45,674,701–45,675,476, 1 gene, copy number 7: PRKCE-AS1.
- chr2:69,013,179–69,249,327, 1 gene, copy number 7 (within-gene range 3–7): ANTXR1.
- chr2:69,103,682–69,437,628, 7 genes, copy number 7–14: MIR3126, RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA, NFU1.
- chr2:69,516,751–69,520,174, 2 genes, copy number 14: RN7SL604P, SNORA36C.
- chr2:120,651,273–121,040,710, 5 genes, copy number 7: Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA.
- chr2:207,186,717–208,358,746, 37 genes, copy number 7 (within-gene range 3–7): AC007879.3, AC007879.5, AC007879.2, AC007879.4, AC009226.1, LINC01802, MIR1302-4, CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2, IDH1, IDH1-AS1, PIKFYVE, MYL6BP1.
- chr2:208,360,631–208,466,626, 2 genes, copy number 7: ARPC1BP1, H3P9.
- chr4:13,977,166–14,242,813, 4 genes, copy number 8: AC095052.1, LINC01085, AC073848.1, AC092546.1.
- chr4:76,306,026–76,802,426, 13 genes, copy number 7: STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1.
- chr5:892,884–1,295,068, 14 genes, copy number 7–46: TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr6:43,705,949–44,155,519, 14 genes, copy number 7–11 (within-gene range 4–11): AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B.
- chr8:126,556,323–127,419,050, 1 gene, copy number 7 (within-gene range 4–7): PCAT1.
- chr8:127,072,694–127,482,139, 8 genes, copy number 7: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr8:144,262,045–144,529,132, 36 genes, copy number 7: BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82.
- chr9:35,406,755–35,865,518, 36 genes, copy number 8–9 (within-gene range 2–9): ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B.
- chr10:122,271,296–122,913,111, 17 genes, copy number 7: BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A.
- chr16:74,999,024–75,648,643, 34 genes, copy number 10 (within-gene range 5–10): ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5.
- chr17:39,461,486–39,864,312, 17 genes, copy number 23–60 (within-gene range 4–60): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr18:48,539,031–49,461,347, 15 genes, copy number 8 (within-gene range 3–8): CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1.
- chr19:29,268,976–30,060,797, 21 genes, copy number 7 (within-gene range 5–7): AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4.
- chr20:45,174,902–45,670,270, 34 genes, copy number 9–10: PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI, MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7, WFDC11.
- chr20:62,427,827–62,643,304, 14 genes, copy number 9: AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1.

Autosomal genes at a single copy (total copy number 1): 165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
